TCGA case TCGA-AD-6964 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5e7074a6-5011-4dc5-950c-41365dbc6d09

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 58 years; Vital status: Dead; Days to death: 331 days.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 58.7 years (21,457 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N2b; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 331 days.
   Pathology details: Circumferential resection margin: 0; Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 16; Lymphatic invasion present: Yes; Non nodal tumor deposits: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Regimen or line of therapy: FOLFOX; Days to treatment start: 63 days; Days to treatment end: 214 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Skin, NOS; Laterality: Right; Classification of tumor: Synchronous primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 59.6 years (21,782 days); Days to diagnosis: 325 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 325 days; Residual disease: RX; Treatment anatomic sites: Other.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Days to follow up: 23 days; Disease response: With Tumor.
- Day 325 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 325 days.
- Days to follow up: 331 days; Disease response: With Tumor.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- MLH1 (IHC): Loss of Expression.
- MSH2 (IHC): Normal.
- MSH6 (IHC): Normal.
- PMS2 (IHC): Loss of Expression.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 91 kg; Height: 183 cm; BMI: 27.2.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AD-6964-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.4; Intermediate dimension: 0.4; Shortest dimension: 0.2.
  Slide TCGA-AD-6964-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 30.
- Sample TCGA-AD-6964-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AD-6964-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Anatomic organ subdivision: Cecum; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 9; Lymphovascular invasion indicator: Yes; Microsatellite instability: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: Yes; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Not Expressed; Mismatch rep proteins loss IHC: MSH2-Expressed; Mismatch rep proteins loss IHC: PMS2-Not Expressed; Mismatch rep proteins loss IHC: MSH6-Expressed.
- Drug treatment: Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Skin w/mets to inguinal LN; Other malignancy histological type: Squamous Cell Carcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: 16.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy SCC of the inguinal lymph nodes. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 331 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 331 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 325 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AD-6964-01A-11D-1923-01): tumor purity 0.5, ploidy 1.99, whole-genome doublings 0.
